Gene-level copy-number profile of tumor specimen TCGA-BT-A3PK-01A from TCGA case TCGA-BT-A3PK, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Posterior wall of bladder; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 80.3 years (29,314 days).
Specimen TCGA-BT-A3PK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.c721f906-f50b-4199-8997-8a6c07b04644.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BT-A3PK-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/58a3bc90-9334-4249-9cc8-65ac3666cefe

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 1: 19,714; copy number 2: 37,597; copy number 3: 1,505; copy number 4: 737; copy number 5: 34; copy number 6: 91; copy number 7: 64; copy number 9: 66; copy number 15: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BT-A3PK-01A-21D-A21Y-01): tumor purity 0.28, ploidy 1.87, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 260 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:38,859,912–38,965,038, 1 gene, copy number 6 (within-gene range 2–6): AL139260.1.
- chr1:38,885,807–42,473,385, 107 genes, copy number 6–9 (within-gene range 2–9) (broad region; genes not listed).
- chr1:42,491,739–42,500,339, 2 genes, copy number 9: RPS3AP11, TMSB4XP1.
- chr4:63,350,114–64,409,468, 3 genes, copy number 7 (within-gene range 4–7): LARP1BP1, AC093730.1, TECRL.
- chr4:71,741,696–77,150,437, 107 genes, copy number 6–9 (broad region; genes not listed).
- chr4:77,216,416–77,216,878, 1 gene, copy number 7: AC008638.3.
- chr6:43,370,026–44,155,519, 34 genes, copy number 5: AL359813.1, AL359813.2, ABCC10, MIR6780B, DLK2, RNU6-1113P, TJAP1, LRRC73, POLR1C, YIPF3, AL355802.3, XPO5, AL355802.1, AL355802.2, POLH, POLH-AS1, GTPBP2, MAD2L1BP, RSPH9, MRPS18A, AL136131.1, AL136131.2, VEGFA, AL136131.3, AL157371.2, LINC02537, AL157371.1, AL109615.3, C6orf223, AL109615.2, AL109615.1, AL109615.4, MRPL14, TMEM63B.
- chr17:39,671,122–39,747,291, 5 genes, copy number 15: PGAP3, ERBB2, MIR4728, MIEN1, GRB7.

Autosomal genes at a single copy (total copy number 1): 17,335. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
